Somatic mutation profile of tumor specimen TCGA-ZF-A9RG-01A (aliquot TCGA-ZF-A9RG-01A-21D-A42E-08) from TCGA case TCGA-ZF-A9RG, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 70.2 years (25,656 days).
Specimen TCGA-ZF-A9RG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22c6bfd5-ca26-4d30-baed-ff975ab3a4e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZF-A9RG-10A (Blood Derived Normal), aliquot TCGA-ZF-A9RG-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb9813e1-8b4f-4ab9-8328-f1adba38aaab

The open-access MAF lists 267 somatic variants for this specimen: 193 protein-altering or splice-affecting, 71 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 171, Silent 71, Nonsense Mutation 14, Splice Site 6, 3'UTR 1, Frame Shift Del 1, 3'Flank 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.*1004A>G | 3'UTR (SNP) | VAF 7/13 reads (54%) | catalogued as rs78311289, CM002967, CM950476, COSV53390625, COSV53407424; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 27/134 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as rs1057519925, COSV55873816, COSV55874585; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by mutect2, varscan2
- TP53 | c.581T>A p.L194H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519998, COSV52663681, COSV52677924, COSV52679257, COSV52713187; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCC5 | c.4063G>A p.E1355K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1358298830, COSV55596821; called by muse, mutect2, varscan2
- ACE2 | c.348G>C p.L116F | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); catalogued as COSV53027525, COSV53027855; called by muse, mutect2, varscan2
- ADAM22 | c.2509G>C p.G837R | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV55991392; called by muse, mutect2, varscan2
- AFDN | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV60057837; called by muse, mutect2, varscan2
- AIF1L | c.171G>A p.M57I | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as COSV55990088; called by muse, mutect2
- AKAP13 | c.4271G>A p.R1424K | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.078); catalogued as COSV63470704; called by muse, mutect2, varscan2
- AMBRA1 | c.2693C>T p.S898F (on ENST00000458649 / NM_001367468.1; = p.S808F on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs1299830189; called by muse, mutect2
- ASH1L | c.5836G>A p.E1946K | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV64214266; called by muse, mutect2, varscan2
- ATAD2 | c.2725G>C p.E909Q | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.028); catalogued as rs1365506359, COSV54880351, COSV54883968, COSV54887139; called by muse, mutect2, varscan2
- ATP13A5 | c.3332C>T p.T1111I | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs1236515873, COSV60873849, COSV60875960; called by muse, mutect2, varscan2
- ATP5F1B | c.949G>C p.E317Q | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV56262214; called by muse, mutect2, varscan2
- ATP5F1B | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 16/99 reads (16%) | catalogued as COSV100007929; called by muse, varscan2
- ATP9A | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58772438; called by muse, mutect2, varscan2
- BANK1 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.294); catalogued as COSV59850290; called by muse, mutect2
- BARD1 | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV53617881, COSV99038470; called by muse, mutect2, varscan2
- BCL11A | c.1664C>T p.S555L (on ENST00000335712 / NM_001365609.1; = p.S589L on NM_018014.4) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.572); catalogued as rs139460584; called by muse, mutect2, varscan2
- BCOR | c.4165G>A p.D1389N (on ENST00000378444 / NM_001123385.2; = p.D1355N on NM_017745.6) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.298); catalogued as rs760406187, COSV60705999, COSV60712737; called by muse, mutect2, varscan2
- BEND2 | c.113C>G p.S38C | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.869); catalogued as COSV66217406, COSV66217414; called by muse, mutect2, varscan2
- BMP5 | c.994C>T p.H332Y | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as rs1399302813, COSV63703525; called by muse, mutect2, varscan2
- BRCA1 | c.2869C>G p.Q957E | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as CM993724, COSV58800613; called by muse, mutect2, varscan2
- C12orf43 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as rs1176572996, COSV56566313, COSV56566816; called by muse, mutect2, varscan2
- C1orf109 | c.565C>G p.L189V | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.168); catalogued as COSV63657218; called by muse, mutect2, varscan2
- C2orf16 | c.4548C>G p.I1516M | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.315); catalogued as COSV62678516; called by muse, mutect2, varscan2
- CATSPERB | c.2438C>G p.S813C | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV56435808; called by muse, mutect2, varscan2
- CCDC150 | c.1373G>A p.G458D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.585); catalogued as rs776380177, COSV55878929; called by mutect2, varscan2
- CCDC198 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs201357909, COSV53602337; called by muse, mutect2, varscan2
- CCDC89 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.066); catalogued as COSV57034938; called by muse, mutect2, varscan2
- CCDC93 | c.356T>C p.V119A | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100098225; called by muse, mutect2
- CCNC | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV100412603, COSV58335002; called by mutect2, varscan2
- CEMIP2 | c.3820G>C p.E1274Q | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.09); catalogued as COSV65489738; called by muse, mutect2, varscan2
- CEP126 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.852); catalogued as rs757955825, COSV54831087; called by muse, mutect2, varscan2
- CHM | c.391A>T p.T131S | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV63304860; called by muse, mutect2, varscan2
- CLCA1 | c.1840A>G p.I614V | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs781270565, COSV52331671; called by muse, mutect2, varscan2
- CLPSL2 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.174); catalogued as COSV64610542; called by muse, mutect2, varscan2
- CMAS | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57557596; called by muse, mutect2, varscan2
- CNNM4 | c.544C>T p.L182F | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.498); catalogued as COSV65660890, COSV65662101; called by muse, mutect2, varscan2
- CNTRL | c.307C>G p.L103V | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53053878; called by muse, mutect2, varscan2
- COL15A1 | c.1375T>G p.L459V | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV66649646; called by muse, mutect2, varscan2
- CREBBP | c.1618C>T p.Q540* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV52128159; called by muse, mutect2, varscan2
- CTNND1 | c.2122C>T p.Q708* (on ENST00000399050 / NM_001085458.2; = p.Q702* on NM_001331.3) | Nonsense Mutation (SNP) | VAF 15/73 reads (21%) | catalogued as COSV100649717; called by muse, mutect2, varscan2
- CYP2C19 | c.1209C>A p.N403K | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as COSV64909586; called by muse, mutect2
- CYP4A22 | c.1169G>A p.G390E | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); catalogued as COSV53738432; called by muse, mutect2
- DHX36 | c.68G>C p.G23A | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.031); catalogued as COSV100273216; called by muse, mutect2
- DNAH3 | c.8110C>T p.Q2704* | Nonsense Mutation (SNP) | VAF 14/97 reads (14%) | catalogued as rs150583804; called by muse, mutect2, varscan2
- DNAH5 | c.6308C>T p.S2103L | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV54254312; called by muse, mutect2, varscan2
- DOP1B | c.5090G>C p.R1697T | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV67692864; called by muse, mutect2
- EDC4 | c.2434G>A p.E812K | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59304012; called by muse, mutect2, varscan2
- EIF2S3 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV53408298; called by muse, mutect2, varscan2
- ELF3 | c.164-1G>A p.X55_splice | Splice Site (SNP) | VAF 7/84 reads (8%) | catalogued as COSV62838303; called by muse, mutect2
- EML1 | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as rs776900171, COSV51753379; called by muse, mutect2, varscan2
- ERBB2 | c.2461G>C p.D821H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.042); catalogued as COSV54078686, COSV54083846; called by muse, mutect2, varscan2
- ERCC2 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV55540161; called by muse, mutect2, varscan2
- FAM13B | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1372112717, COSV50374948; called by muse, mutect2, varscan2
- FAM161B | c.1618G>A p.D540N (on ENST00000651776; = p.D477N on NM_152445.3) | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.065); catalogued as rs370193329; called by muse, mutect2, varscan2
- FAM221A | c.524G>A p.R175K | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61388661; called by muse, mutect2, varscan2
- FAM91A1 | c.1754C>G p.S585* | Nonsense Mutation (SNP) | VAF 30/141 reads (21%) | catalogued as COSV100593410; called by muse, mutect2, varscan2
- FAT3 | c.8302G>A p.D2768N | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as COSV53178414; called by muse, mutect2, varscan2
- FAT4 | c.9544G>T p.V3182L | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV58710425; called by muse, mutect2
- FER1L6 | c.2885C>T p.S962F | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.584); catalogued as COSV67552959; called by muse, mutect2, varscan2
- FIGNL1 | c.1406C>T p.S469F | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1210958309, COSV100794813; called by muse, mutect2
- G3BP2 | c.296C>A p.S99Y | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV62977782; called by muse, mutect2
- GLDC | c.1475C>T p.S492L | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1315965351, COSV58685577; called by muse, mutect2, varscan2
- GLIS1 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs1243165573, COSV56557226; called by muse, mutect2, varscan2
- GORAB | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV63026977; called by muse, mutect2, varscan2
- GPATCH3 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64652756; called by muse, mutect2
- GPR35 | c.785G>C p.S262T | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.118); catalogued as rs1425883078, COSV60578749; called by muse, mutect2, varscan2
- GREB1 | c.2469G>C p.Q823H | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52197055; called by muse, mutect2, varscan2
- GRIK3 | c.237G>C p.L79F | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV66147194, COSV66147454; called by muse, mutect2
- H1-4 | c.636G>C p.K212N | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56803671; called by muse, mutect2, varscan2
- HARS1 | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56909099; called by muse, mutect2, varscan2
- HEATR1 | c.3861G>C p.L1287F | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1558182997, COSV63982908; called by muse, mutect2, varscan2
- HERC1 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.34); catalogued as COSV101496283; called by muse, mutect2
- HYDIN | c.2662G>T p.E888* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100376363, COSV100378917; called by mutect2, varscan2
- IQCH | c.1241G>A p.R414Q | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs781051273, COSV60060438; called by muse, mutect2, varscan2
- IQCH | c.1908G>A p.M636I | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV60060452; called by muse, mutect2, varscan2
- ITPKC | c.1320C>G p.S440R | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs370620477, COSV54577532; called by muse, mutect2, varscan2
- KCNH7 | c.130T>A p.C44S | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59814798; called by muse, mutect2, varscan2
- KDM3A | c.1424C>T p.S475L | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as rs201713531, COSV57225900; called by muse, mutect2, varscan2
- KDM6A | c.2587C>T p.Q863* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as COSV65038473, COSV65045993; called by muse, mutect2, varscan2
- KMT2E | c.2107G>A p.E703K | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.118); catalogued as COSV57579083; called by muse, mutect2, varscan2
- KMT2E | c.4952C>T p.S1651F | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as COSV57568958, COSV57580242; called by muse, mutect2, varscan2
- KMT5B | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 47/195 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV58569913; called by muse, mutect2, varscan2
- LCMT1 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs1044820578, COSV66727132; called by muse, mutect2, varscan2
- LEMD3 | c.1915T>C p.C639R | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.845); catalogued as COSV57654113; called by muse, mutect2, varscan2
- LRPPRC | c.2516C>T p.S839F | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as rs1237064273, COSV53243621; called by muse, mutect2, varscan2
- LRRC37A2 | c.3958A>G p.K1320E | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs781291614, COSV60236780; called by muse, mutect2, varscan2
- LYPD3 | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99746813; called by muse, mutect2
- MAP1B | c.4480G>A p.E1494K | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as COSV57107071; called by muse, mutect2, varscan2
- MAPKAP1 | c.1508G>C p.R503T (on ENST00000265960 / NM_001006617.3; = p.R467T on NM_024117.3) | Missense Mutation (SNP) | VAF 64/116 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV56367557; called by muse, mutect2, varscan2
- METTL23 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV57976053; called by muse, mutect2, varscan2
- METTL8 | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.544); catalogued as rs142842112; called by muse, mutect2, varscan2
- MORC4 | c.1751C>G p.T584R | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.276); catalogued as COSV55246841; called by muse, mutect2
- MRM3 | c.942G>A p.M314I | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV58680918; called by muse, mutect2, varscan2
- MUC16 | c.3556G>A p.E1186K | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.583); catalogued as COSV67479967, COSV67496354; called by muse, mutect2, varscan2
- MYCBPAP | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60412620; called by muse, mutect2, varscan2
- MYH15 | c.3223C>T p.R1075W | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs201356810; called by muse, mutect2, varscan2
- MYOF | c.3696C>G p.F1232L | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs1408412173, COSV63711119; called by muse, mutect2, varscan2
- MYOG | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs1377246759, COSV99613792; called by muse, mutect2, varscan2
- NBEAL1 | c.7678G>A p.E2560K | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.967); catalogued as COSV68917137; called by muse, mutect2
- NBPF3 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs201304277, COSV59060654; called by muse, mutect2, varscan2
- NECTIN3 | c.1204A>G p.I402V | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs373638334; called by mutect2, varscan2
- NFKBIZ | c.1444-1G>A p.X482_splice | Splice Site (SNP) | VAF 9/31 reads (29%) | catalogued as COSV58201029, COSV58202105; called by muse, mutect2, varscan2
- NOTCH4 | c.5200+2T>C p.X1734_splice | Splice Site (SNP) | VAF 16/112 reads (14%) | catalogued as COSV66684070; called by muse, mutect2, varscan2
- NUP160 | c.2447-1G>A p.X816_splice | Splice Site (SNP) | VAF 4/30 reads (13%) | catalogued as COSV101021213; called by muse, mutect2
- NUP88 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs745395510, COSV56708135; called by muse, mutect2, varscan2
- OAS1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as COSV52538986; called by muse, mutect2, varscan2
- OR5B21 | c.61C>A p.L21I | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.755); catalogued as COSV100835082, COSV100835114, COSV64482300; called by muse, mutect2, varscan2
- PAAF1 | c.308G>A p.R103K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as COSV100142276; called by muse, mutect2
- PALM2AKAP2 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV57114308; called by muse, mutect2, varscan2
- PAN2 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.445); catalogued as COSV99228034; called by muse, mutect2
- PARP4 | c.4859G>C p.R1620T | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV67964404; called by muse, mutect2, varscan2
- PCDHA12 | c.1342G>A p.V448M | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as rs571648883, COSV56475315; called by muse, mutect2, varscan2
- PDF | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV54752268; called by muse, mutect2, varscan2
- PDZRN3 | c.3086G>A p.R1029K | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as rs780710627, COSV55216378, COSV99731800; called by muse, mutect2, varscan2
- PEX6 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as rs1425285857, COSV55105719; called by muse, mutect2, varscan2
- PIK3C2B | c.2015G>A p.R672Q | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs764826798, COSV65814449; called by muse, mutect2
- PIK3C3 | c.1328C>T p.S443F | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV100010071; called by muse, mutect2
- PIWIL4 | c.154A>G p.I52V | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV54412763; called by muse, mutect2
- PMS2 | c.871T>A p.F291I | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV56224362; called by muse, mutect2
- PNLDC1 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV51708327, COSV99277226; called by muse, mutect2
- PRPF4 | c.1445C>T p.S482F (on ENST00000374198 / NM_001322267.2; = p.S483F on NM_004697.5) | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0.413); catalogued as COSV65253498; called by muse, mutect2, varscan2
- PTPN3 | c.2231C>T p.T744M | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750440450, COSV52706432; called by muse, mutect2, varscan2
- PTPRF | c.3283A>C p.T1095P | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63449150; called by muse, mutect2, varscan2
- RIMKLA | c.1009G>C p.E337Q | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.424); catalogued as COSV101290559, COSV68910003; called by muse, mutect2, varscan2
- RIMS4 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV65720847; called by muse, mutect2, varscan2
- RLIM | c.848G>A p.R283K | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as COSV60329321; called by muse, mutect2, varscan2
- ROS1 | c.597G>C p.L199F | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV63861331, COSV63862023; called by muse, mutect2, varscan2
- RPL4 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.597); catalogued as COSV57183459; called by muse, mutect2
- RXRG | c.516C>G p.I172M | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV63233188; called by muse, mutect2, varscan2
- SALL2 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV58102461, COSV58106000; called by muse, mutect2, varscan2
- SCAF11 | c.4022C>T p.S1341L | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs768285235, COSV65479288; called by muse, mutect2, varscan2
- SCN3A | c.3511G>A p.E1171K | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.323); catalogued as COSV51810880; called by muse, mutect2, varscan2
- SEC31B | c.382G>C p.D128H | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104427491, COSV64825199; called by muse, mutect2
- SEPSECS | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57207808; called by muse, mutect2, varscan2
- SETDB1 | c.79C>T p.Q27* | Nonsense Mutation (SNP) | VAF 7/75 reads (9%) | catalogued as COSV99643470; called by muse, mutect2, varscan2
- SF3B3 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV56790171; called by muse, mutect2, varscan2
- SH2D4A | c.353C>G p.S118C | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as rs777774445, COSV56125055; called by muse, mutect2, varscan2
- SHANK3 | c.2270C>G p.P757R | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV53191570; called by muse, mutect2, varscan2
- SIK3 | c.553G>T p.A185S (on ENST00000445177 / NM_001366686.2; = p.A191S on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99407100; called by muse, mutect2
- SIPA1L2 | c.4058C>T p.S1353L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.813); catalogued as COSV53400656; called by muse, mutect2, varscan2
- SLC13A4 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs563522177, COSV62460480, COSV62461946; called by muse, mutect2, varscan2
- SLC16A3 | c.1375C>T p.H459Y | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs1279754466, COSV58366553; called by muse, mutect2, varscan2
- SLC4A8 | c.433G>C p.D145H | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100176329; called by muse, mutect2
- SMG1 | c.5822A>G p.N1941S | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as COSV67174974; called by muse, mutect2, varscan2
- SNRPA1 | c.395G>A p.R132K | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54258618; called by muse, mutect2, varscan2
- SPAG16 | c.1453G>C p.E485Q | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.998); catalogued as COSV59075127, COSV59120865, COSV59129802; called by muse, mutect2, varscan2
- SRD5A1 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.832); catalogued as rs1309203082, COSV99242845; called by muse, mutect2, varscan2
- SSTR1 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.693); catalogued as rs1301975112, COSV57455038; called by muse, mutect2, varscan2
- SWAP70 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs1192884138, COSV59667165; called by muse, mutect2, varscan2
- SYTL3 | c.1489G>C p.D497H (on ENST00000611299 / NM_001242394.1; = p.D429H on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); catalogued as COSV51915486, COSV51916092; called by muse, mutect2, varscan2
- SYTL3 | c.1717G>A p.G573S (on ENST00000611299 / NM_001242394.1; = p.G505S on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs1249653036, COSV51915499; called by muse, mutect2, varscan2
- TACC2 | c.5410C>T p.H1804Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1480430073, COSV57774520; called by muse, mutect2, varscan2
- TBC1D10C | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs141022722; called by muse, mutect2
- TENT5D | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as COSV100382522; called by muse, mutect2, varscan2
- TFCP2 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV56936320; called by muse, mutect2, varscan2
- TMEM17 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as rs1421689113, COSV100107630; called by muse, mutect2
- TMEM19 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV57001283; called by muse, mutect2, varscan2
- TNIK | c.3611G>A p.R1204K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV99454327, COSV99457099; called by muse, mutect2
- TNS3 | c.1303G>C p.E435Q | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60799885; called by muse, mutect2, varscan2
- TNS4 | c.1317G>A p.M439I | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV54188310; called by muse, mutect2, varscan2
- TRAPPC9 | c.2239G>C p.E747Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV66910201; called by muse, mutect2, varscan2
- TRAV6 | c.284A>G p.E95G | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); catalogued as rs1295557329; called by muse, mutect2, varscan2
- TRERF1 | c.2590G>T p.E864* | Nonsense Mutation (SNP) | VAF 16/93 reads (17%) | catalogued as COSV100549740, COSV61678570; called by muse, mutect2, varscan2
- TRIOBP | c.2765C>G p.S922C | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV60380912; called by muse, mutect2
- TRIOBP | c.3319C>T p.Q1107* | Nonsense Mutation (SNP) | VAF 13/79 reads (16%) | catalogued as COSV60375813; called by muse, mutect2, varscan2
- TSSK1B | c.433G>C p.D145H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66816162; called by muse, mutect2, varscan2
- TTF2 | c.3184C>T p.Q1062* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as COSV101037153, COSV101037172; called by muse, mutect2, varscan2
- TTN | c.19442A>T p.K6481M (on ENST00000591111; = p.K5554M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | PolyPhen benign (0.434); catalogued as COSV60369031; called by muse, mutect2, varscan2
- TUBE1 | c.958G>C p.D320H | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57890629; called by muse, mutect2, varscan2
- TXLNB | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs780421879, COSV100625089, COSV64443688; called by muse, mutect2, varscan2
- USP48 | c.2592C>G p.I864M | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV57615056; called by muse, mutect2, varscan2
- VGLL3 | c.784C>A p.L262M | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1437906453, COSV67354567; called by mutect2, varscan2
- WDR43 | c.1379A>G p.N460S | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV56100008; called by muse, mutect2, varscan2
- WDR44 | c.2167-1G>T p.X723_splice | Splice Site (SNP) | VAF 9/103 reads (9%) | catalogued as COSV54169528; called by muse, mutect2
- WIF1 | c.626G>A p.C209Y | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54136157; called by muse, varscan2
- ZC3H12C | c.1871C>G p.S624C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99584542; called by muse, mutect2
- ZCWPW1 | c.1225C>T p.Q409* | Nonsense Mutation (SNP) | VAF 36/162 reads (22%) | catalogued as COSV99546244; called by muse, mutect2, varscan2
- ZNF214 | c.1689C>G p.F563L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV53483844; called by muse, mutect2, varscan2
- ZNF277 | c.11C>A p.S4Y | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as rs1221866338, COSV62466365; called by muse, mutect2, varscan2
- ZNF609 | c.283A>C p.S95R | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV58590718; called by muse, mutect2, varscan2
- ZNF718 | c.573A>T p.R191S | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.487); catalogued as COSV101210217; called by muse, mutect2
- ZNF773 | c.234G>T p.W78C | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56590596; called by muse, mutect2, varscan2
- ZNF793 | c.677C>G p.P226R | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV101495626; called by muse, mutect2
- ZNF92 | c.1565C>G p.S522* (on ENST00000328747 / NM_152626.4; = p.S453* on NM_007139.4) | Nonsense Mutation (SNP) | VAF 9/69 reads (13%) | catalogued as COSV100165626; called by muse, mutect2
- ZRANB3 | c.2990C>T p.S997L | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV51516871; called by muse, mutect2, varscan2
- ANK3 | c.2968del p.V990Wfs*8 (on ENST00000280772 / NM_001320874.2; = p.V124Wfs*8 on NM_001149.3) | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, varscan2
- PCGF2 | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2
- SLC39A5 | c.1031_1039del p.Q344_A346del | In Frame Del (DEL) | VAF 8/31 reads (26%) | called by mutect2, pindel, varscan2
- STAG2 | c.385_385+8del p.X129_splice | Splice Site (DEL) | VAF 10/97 reads (10%) | called by mutect2, pindel
- ZFYVE16 | c.467C>G p.S156C | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2
- AASDHPPT | c.297G>A p.S99= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV53788290, COSV99593323; called by muse, mutect2, varscan2
- AASDHPPT | c.606A>C p.L202= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as rs765718892, COSV53788526, COSV53790641; called by muse, mutect2, varscan2
- ABCC5 | c.114C>T p.F38= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV55596832; called by muse, mutect2, varscan2
- ACAP2 | c.177C>T p.F59= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as rs1269727974, COSV58756117; called by muse, mutect2, varscan2
- ACBD5 | c.1335C>T p.L445= (on ENST00000375888 / NM_001352568.1; = p.L436= on NM_145698.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as rs1221445450, COSV65521418; called by muse, mutect2, varscan2
- ACSBG2 | c.726C>T p.L242= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV53127952; called by muse, mutect2, varscan2
- AHNAK | c.8070G>A p.L2690= | Silent (SNP) | VAF 45/183 reads (25%) | catalogued as COSV57231897; called by muse, mutect2, varscan2
- AP1M2 | c.327C>T p.I109= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs1379433839, COSV51569672, COSV99140947; called by muse, mutect2, varscan2
- APOL5 | c.246G>A p.L82= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV50768707; called by muse, mutect2, varscan2
- AQP11 | c.459C>T p.F153= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV57993272; called by muse, mutect2, varscan2
- ARSD | c.1242G>C p.L414= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV54203363; called by muse, mutect2, varscan2
- ATP10A | c.2814C>A p.G938= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV63525174; called by muse, mutect2, varscan2
- B3GNT2 | c.897C>G p.L299= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as rs988654547, COSV57345938; called by muse, mutect2
- BIRC6 | c.2577C>G p.L859= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV70199244; called by muse, mutect2, varscan2
- CADM2 | c.1302C>T p.F434= (on ENST00000407528 / NM_001167674.2; = p.F436= on NM_153184.4) | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs1486691794, COSV67406633; called by muse, mutect2, varscan2
- CAPN1 | c.351C>G p.L117= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV54201671; called by muse, mutect2
- CARMIL3 | c.234C>T p.L78= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV57728523; called by muse, mutect2, varscan2
- CHRM2 | c.783G>A p.Q261= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV57777369; called by muse, mutect2, varscan2
- CLDN6 | c.39G>C p.L13= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV58509773, COSV58510760; called by muse, mutect2
- CLDN9 | c.531C>T p.G177= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs987098263, COSV60911742; called by muse, mutect2, varscan2
- DBF4 | c.21G>A p.R7= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV99719092; called by muse, mutect2
- DHX36 | c.171G>A p.L57= | Silent (SNP) | VAF 17/111 reads (15%) | catalogued as COSV57677533; called by muse, mutect2, varscan2
- DUOX1 | c.4362C>T p.I1454= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV52052865; called by muse, mutect2, varscan2
- ECHS1 | c.147G>A p.L49= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV63907545; called by muse, mutect2, varscan2
- EPB41L3 | c.231C>T p.L77= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs753802215, COSV59462357, COSV59468776; called by muse, mutect2, varscan2
- F8 | c.2013C>T p.F671= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as CM0910969, COSV64279040; called by muse, mutect2, varscan2
- FGD3 | c.921C>T p.L307= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV61600151; called by muse, mutect2, varscan2
- FSTL3 | c.243C>T p.I81= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV51261514; called by muse, mutect2, varscan2
- GNA13 | c.399C>T p.A133= | Silent (SNP) | VAF 20/215 reads (9%) | catalogued as rs899948127, COSV71475269; called by muse, mutect2
- GTF2F1 | c.1452G>A p.L484= | Silent (SNP) | VAF 32/142 reads (23%) | catalogued as COSV55532611, COSV55532954; called by muse, mutect2, varscan2
- HNRNPA1 | c.90G>A p.L30= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs747731298, COSV52937987; called by muse, mutect2, varscan2
- HSPB2 | c.204G>A p.R68= | Silent (SNP) | VAF 6/71 reads (8%) | catalogued as COSV57052929; called by muse, mutect2
- IQGAP2 | c.1182C>T p.L394= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV57183285; called by muse, mutect2, varscan2
- KAT2B | c.2385C>T p.V795= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV55434954; called by muse, mutect2, varscan2
- LARP1B | c.1326C>T p.D442= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs1261192947, COSV52803344; called by muse, mutect2, varscan2
- LRRC14 | c.1068C>T p.F356= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV52883005; called by muse, mutect2, varscan2
- LRRFIP1 | c.966G>A p.E322= (on ENST00000392000 / NM_001137552.2; = p.E298= on NM_004735.4) | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV55257287; called by muse, mutect2, varscan2
- MB21D2 | c.1475G>A p.*492= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV101164964; called by muse, mutect2, varscan2
- MCF2L | c.259C>A p.R87= (on ENST00000375608; = p.R55= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV65051902, COSV65054184; called by muse, mutect2, varscan2
- MFSD4A | c.1446C>T p.I482= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as rs1356964894, COSV100901721, COSV65657136; called by muse, mutect2, varscan2
- MRPL35 | c.471C>T p.L157= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV51257558; called by muse, mutect2, varscan2
- MYH6 | c.1282C>T p.L428= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV62454778; called by muse, mutect2, varscan2
- OCEL1 | c.792C>T p.F264= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV52243889; called by muse, mutect2, varscan2
- OR10J1 | c.474G>A p.T158= | Silent (SNP) | VAF 13/118 reads (11%) | catalogued as rs149860482, COSV71128517; called by muse, mutect2, varscan2
- OR6K3 | c.792G>C p.P264= (on ENST00000368146; = p.P248= on NM_001005327.2) | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV63746124, COSV63746593; called by muse, mutect2, varscan2
- PAH | c.111G>A p.L37= | Silent (SNP) | VAF 25/108 reads (23%) | catalogued as rs867922368, COSV61020701; called by muse, mutect2, varscan2
- PCDH19 | c.1434C>T p.R478= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs137962077, COSV55272100; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- PCDHGB7 | c.252A>G p.L84= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as rs763834283, COSV54040263; called by muse, mutect2, varscan2
- PPFIA3 | c.3372C>T p.F1124= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV53257688; called by mutect2, varscan2
- PPP1R15B | c.201C>G p.L67= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV65816613; called by muse, mutect2, varscan2
- PRR35 | c.1479G>A p.L493= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV99215576; called by muse, mutect2, varscan2
- PRRT1 | c.606C>G p.L202= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99278141; called by muse, mutect2
- PTPN7 | c.480G>A p.G160= (on ENST00000495688; = p.G199= on NM_002832.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100459568, COSV100460209; called by muse, mutect2
- RAPGEF4 | c.2811G>A p.G937= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV51417487; called by muse, mutect2
- RASA2 | c.597A>C p.L199= | Silent (SNP) | VAF 8/120 reads (7%) | catalogued as COSV53946816; called by muse, mutect2
- RNF168 | c.1497C>T p.F499= | Silent (SNP) | VAF 72/289 reads (25%) | catalogued as COSV58839644; called by muse, mutect2, varscan2
- SERPINA9 | c.732G>A p.E244= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV54078604; called by muse, mutect2, varscan2
- SGSM1 | c.3120G>A p.L1040= (on ENST00000400359 / NM_001039948.4; = p.L979= on NM_133454.3) | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV68513957; called by muse, mutect2, varscan2
- SIX1 | c.609C>G p.L203= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs1404357119, COSV55961327, COSV55961423; called by muse, mutect2, varscan2
- SLC12A2 | c.2052A>G p.A684= | Silent (SNP) | VAF 5/92 reads (5%) | catalogued as rs1431331836, COSV99320426; called by muse, mutect2
- SPAG9 | c.2355C>T p.F785= (on ENST00000262013 / NM_001130528.3; = p.F771= on NM_003971.6) | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV56244421; called by muse, mutect2, varscan2
- THYN1 | c.240C>G p.L80= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV55542826; called by muse, mutect2, varscan2
- TLN2 | c.2799G>A p.Q933= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV100167750; called by muse, mutect2
- TMEM41A | c.771T>C p.H257= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs748851535, COSV53998257; called by muse, varscan2
- TMEM94 | c.879C>T p.L293= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV58600395; called by muse, mutect2, varscan2
- TNFAIP8 | c.387C>T p.S129= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV57229714; called by muse, mutect2, varscan2
- TSR1 | c.1593G>A p.Q531= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs575906987, COSV56787421; called by muse, mutect2, varscan2
- XKRX | c.651C>T p.T217= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV60709400; called by muse, mutect2
- XPO6 | c.2589G>A p.Q863= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV58971974; called by muse, mutect2, varscan2
- ZNF383 | c.1395C>T p.L465= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as rs751811198, COSV61940241; called by muse, mutect2, varscan2
- ZNF551 | c.1722C>G p.L574= | Silent (SNP) | VAF 25/116 reads (22%) | catalogued as COSV56594728; called by muse, mutect2, varscan2
- COMMD9 | chr11:36271707 G>C | 3'Flank (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- NIN | c.-21-1216C>T | Intron (SNP) | VAF 14/58 reads (24%) | catalogued as COSV99811125; called by muse, mutect2, varscan2
